Somatic mutation profile of tumor specimen 0DYTS3 from CCDI case PBCTBU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,109 days).
Specimen 0DYTS3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d93df81-dbab-4c7f-9c88-19cce1cb7432.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYTRN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5713f3f0-4433-4728-b7ae-683f0da638a7

The open-access MAF lists 48 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Intron 9, Splice Region 2, RNA 2, Nonsense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 155/336 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRD7 | c.1367C>G p.P456R | Missense Mutation (SNP) | VAF 234/532 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV67158819; called by muse, mutect2, varscan2
- DAPK2 | c.16A>G p.M6V | Missense Mutation (SNP) | VAF 36/587 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs138812766; called by muse, mutect2
- ESR1 | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1371066167; called by muse, mutect2, varscan2
- HERC5 | c.2297G>T p.R766I | Missense Mutation (SNP) | VAF 36/602 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV52037177; called by muse, mutect2
- MUC17 | c.3779C>T p.P1260L | Missense Mutation (SNP) | VAF 136/376 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV60291847; called by muse, mutect2, varscan2
- PHC2 | c.2548G>C p.A850P (on ENST00000257118 / NM_198040.2; = p.A315P on NM_004427.4) | Missense Mutation (SNP) | VAF 33/646 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930630; called by muse, mutect2
- RALGAPB | c.2322G>A p.W774* | Nonsense Mutation (SNP) | VAF 41/798 reads (5%) | catalogued as rs1200532490; called by muse, mutect2
- SGSM1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 277/606 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs776359686; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2
- TAAR6 | c.718T>A p.S240T | Missense Mutation (SNP) | VAF 100/144 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV51583298; called by muse, mutect2, varscan2
- TKFC | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 200/365 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as rs754541667; called by muse, mutect2, varscan2
- TRIM49B | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 148/480 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs754589516, COSV60319963, COSV99081987; called by muse, mutect2, varscan2
- ZBTB7A | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 108/365 reads (30%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as rs753845110; called by muse, mutect2, varscan2
- AMIGO2 | c.88A>C p.T30P | Missense Mutation (SNP) | VAF 52/515 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.102); called by muse, mutect2
- C12orf50 | c.291T>A p.D97E | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.124); called by muse, mutect2
- CCDC71 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 159/403 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CORIN | c.394A>G p.S132G | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- CSNK2B | c.368-6T>A | Splice Region (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- DDX3X | c.1167+5T>A | Splice Region (SNP) | VAF 32/431 reads (7%) | called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 38/784 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RFX7 | c.2422T>G p.S808A (on ENST00000559447 / NM_001368074.1; = p.S905A on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2
- RPA4 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 14/293 reads (5%) | called by muse, mutect2
- TFB2M | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 150/257 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TRRAP | c.3337G>T p.V1113L | Missense Mutation (SNP) | VAF 67/734 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ARHGAP29 | c.3180C>T p.D1060= | Silent (SNP) | VAF 170/414 reads (41%) | catalogued as rs780050775, COSV53115996; called by muse, varscan2
- CENPT | c.165A>G p.T55= | Silent (SNP) | VAF 273/583 reads (47%) | called by muse, mutect2, varscan2
- CFAP46 | c.2763G>A p.V921= | Silent (SNP) | VAF 34/324 reads (10%) | called by muse, mutect2, varscan2
- CIAO1 | c.795G>A p.G265= | Silent (SNP) | VAF 265/597 reads (44%) | called by muse, mutect2, varscan2
- GATAD2B | c.180A>G p.P60= | Silent (SNP) | VAF 154/446 reads (35%) | called by muse, varscan2
- HEATR5B | c.3768T>C p.C1256= | Silent (SNP) | VAF 16/426 reads (4%) | catalogued as rs972514452; called by muse, mutect2
- KCNJ4 | c.252C>T p.H84= | Silent (SNP) | VAF 156/496 reads (31%) | catalogued as rs140389222; called by muse, mutect2
- PPM1K | c.1002T>C p.G334= | Silent (SNP) | VAF 46/364 reads (13%) | called by muse, mutect2, varscan2
- RTN3 | c.1011C>T p.N337= (on ENST00000377819 / NM_001265589.2; = p.N318= on NM_201428.3) | Silent (SNP) | VAF 44/387 reads (11%) | catalogued as rs867805352; called by muse, varscan2
- TRPM6 | c.5004C>A p.L1668= | Silent (SNP) | VAF 44/394 reads (11%) | catalogued as COSV62510184; called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 8/88 reads (9%) | catalogued as rs1262556378; called by muse, mutect2
- ABR | c.1851+30G>C | Intron (SNP) | VAF 75/397 reads (19%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 18/145 reads (12%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 18/144 reads (13%) | called by muse, varscan2
- FIBP | c.667+15C>A | Intron (SNP) | VAF 39/302 reads (13%) | called by mutect2, varscan2
- HDAC4 | c.2218+100C>A | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as COSV61866592; called by mutect2, varscan2
- HDAC4 | c.2218+98del | Intron (DEL) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- RAD51C | c.1026+35T>G | Intron (SNP) | VAF 44/402 reads (11%) | called by muse, mutect2, varscan2
- RPS3AP24 | n.304A>G | RNA (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- TPM2 | chr9:35682261 T>C | 3'Flank (SNP) | VAF 16/367 reads (4%) | called by muse, mutect2
